Somatic mutation profile of tumor specimen TARGET-30-PASEGA-01A (aliquot TARGET-30-PASEGA-01A-01D) from TARGET case TARGET-30-PASEGA, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 3.0 years (1,091 days).
Specimen TARGET-30-PASEGA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c95c2093-5b48-4beb-a468-1d0b25c047b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASEGA-10A (Blood Derived Normal), aliquot TARGET-30-PASEGA-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3575eb78-7e57-4ed6-a41a-8f91ee537a6e

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACHD1 | c.3565T>G p.S1189A | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.746); catalogued as COSV51559673; called by muse, mutect2, varscan2
- DNAH11 | c.2619dup p.Y874Ifs*19 | Frame Shift Ins (INS) | VAF 16/92 reads (17%) | catalogued as rs1272994000; called by mutect2, varscan2
- FRYL | c.2390G>A p.G797D | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51961281; called by muse, mutect2, varscan2
- FZD6 | c.1703A>G p.H568R | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as rs1160809849, COSV62472579; called by muse, mutect2, varscan2
- FZR1 | c.698C>A p.T233N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV58053577; called by muse, mutect2
- IMMT | c.1270G>T p.A424S | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV54490044; called by muse, mutect2, varscan2
- ING4 | c.631G>A p.G211S (on ENST00000396807 / NM_001127582.2; = p.G210S on NM_016162.4) | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57525290; called by muse, mutect2, varscan2
- MUC16 | c.17587A>C p.N5863H | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as rs370214870; called by muse, mutect2, varscan2
- RNF31 | c.2263G>T p.D755Y | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV60728547; called by muse, mutect2, varscan2
- SCNN1D | c.238G>A p.G80R (on ENST00000338555; = p.G244R on NM_001130413.4) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs369500498; called by muse, mutect2, varscan2
- SF3B1 | c.3193C>A p.L1065I | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as COSV59226584; called by muse, mutect2, varscan2
- SPTA1 | c.6469G>T p.E2157* | Nonsense Mutation (SNP) | VAF 45/239 reads (19%) | catalogued as COSV63754347; called by muse, mutect2, varscan2
- TRPV4 | c.2388C>A p.N796K | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.056); catalogued as COSV55686472; called by muse, mutect2, varscan2
- WDR26 | c.1946G>C p.G649A (on ENST00000414423 / NM_001379403.1; = p.G549A on NM_025160.7) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); catalogued as COSV54359988; called by muse, mutect2, varscan2
- BCAN | c.1156A>T p.T386S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CNOT6 | c.1314G>A p.K438= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs368152537; called by muse, mutect2, varscan2
- MTHFSD | c.414G>C p.V138= (on ENST00000360900 / NM_001159377.2; = p.V137= on NM_022764.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV59804685; called by mutect2, varscan2
- SLC7A7 | c.492C>T p.A164= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV53542450; called by muse, mutect2, varscan2
- SPTA1 | c.93G>C p.V31= | Silent (SNP) | VAF 35/202 reads (17%) | catalogued as COSV63758854; called by muse, mutect2, varscan2
- TUBA3E | c.690G>C p.L230= | Silent (SNP) | VAF 33/168 reads (20%) | catalogued as COSV56059826; called by muse, mutect2, varscan2
